Somatic mutation profile of tumor specimen MMRF_2288_1_BM_CD138pos (aliquot MMRF_2288_1_BM_CD138pos_T2_KHS5U_K14061) from MMRF case MMRF_2288, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.4 years (21,681 days).
Specimen MMRF_2288_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3e365e1-5855-48e2-9529-5b989554d5ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2288_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2288_1_PB_Whole_C1_KHS5U_K14060; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7c380a3-870c-4e1a-9768-50c72fc5f2c4

The open-access MAF lists 60 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 14, Silent 9, Intron 7, 5'UTR 4, Frame Shift Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA2 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.084); catalogued as rs141027815; called by muse, mutect2
- FAM3A | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100453597; called by muse, mutect2, varscan2
- FMN2 | c.2881G>T p.G961W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60447269; called by muse, mutect2, varscan2
- HAND1 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50562409; called by muse, mutect2
- IGSF1 | c.2480C>T p.P827L | Missense Mutation (SNP) | VAF 95/172 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs376887010; called by muse, mutect2, varscan2
- LIPN | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68383970; called by muse, mutect2
- LRRIQ1 | c.1299G>T p.K433N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV101280322; called by muse, mutect2, varscan2
- MARK1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1188353429; called by muse, mutect2, varscan2
- OTOF | c.5374C>T p.R1792C (on ENST00000272371 / NM_194248.3; = p.R1025C on NM_004802.4) | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs142111099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU4F1 | c.64T>C p.Y22H | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65884341; called by muse, mutect2, varscan2
- TCTEX1D4 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs746024768; called by muse, mutect2
- USP35 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.459); catalogued as COSV101489041; called by mutect2, varscan2
- C7 | c.1274A>T p.Y425F | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- FDPS | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR52R1 | c.667A>C p.M223L | Missense Mutation (SNP) | VAF 160/170 reads (94%) | SIFT tolerated (0.85); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PIKFYVE | c.2086A>G p.S696G | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, varscan2
- POGLUT3 | c.742C>G p.R248G | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- RNF19B | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ROBO2 | c.3833C>A p.A1278D | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2
- SESN3 | c.40T>C p.Y14H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.136); called by muse, varscan2
- SRSF5 | c.419_435del p.H140Rfs*5 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- SYN1 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX51 | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ZNF711 | c.2101A>G p.R701G | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ADGRG2 | c.1005C>T p.S335= (on ENST00000379869 / NM_001079858.3; = p.S332= on NM_005756.4) | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as rs1467011232, COSV100492791; called by muse, mutect2
- C4orf17 | c.522A>G p.P174= | Silent (SNP) | VAF 48/277 reads (17%) | called by muse, mutect2, varscan2
- DCN | c.945T>A p.P315= | Silent (SNP) | VAF 120/276 reads (43%) | catalogued as rs752356761; called by muse, mutect2, varscan2
- DNAH9 | c.990G>A p.E330= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as COSV52375113; called by muse, mutect2, varscan2
- IQGAP2 | c.1144T>C p.L382= | Silent (SNP) | VAF 187/281 reads (67%) | called by muse, mutect2, varscan2
- LONP1 | c.2217C>T p.P739= | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as rs370435213; called by muse, mutect2, varscan2
- MTMR10 | c.714G>C p.G238= | Silent (SNP) | VAF 40/265 reads (15%) | called by muse, mutect2, varscan2
- PEX5 | c.1035C>T p.R345= (on ENST00000420616; = p.R337= on NM_000319.5) | Silent (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- TJP1 | c.141C>T p.R47= | Silent (SNP) | VAF 60/173 reads (35%) | catalogued as rs760208708; called by muse, mutect2, varscan2
- ADH6 | c.-39C>A | 5'UTR (SNP) | VAF 99/219 reads (45%) | catalogued as COSV99421979; called by muse, mutect2, varscan2
- AR | c.*820C>A | 3'UTR (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- CALN1 | c.*1557G>T | 3'UTR (SNP) | VAF 54/189 reads (29%) | called by muse, mutect2, varscan2
- CCNL2 | c.660-57C>T | Intron (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- CFAP20DC | c.-88C>A | 5'UTR (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- COL6A5 | c.*541T>C | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- DNAJC2 | c.-67G>A | 5'UTR (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- DTX1 | c.-451C>T | 5'UTR (SNP) | VAF 11/20 reads (55%) | catalogued as rs988666721; called by muse, mutect2
- FGFR2 | c.*661dup | 3'UTR (INS) | VAF 14/32 reads (44%) | catalogued as rs533680275; called by mutect2, varscan2
- FXN | c.*468G>A | 3'UTR (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- HERC2P2 | n.4048C>T | RNA (SNP) | VAF 26/125 reads (21%) | catalogued as rs1225391988; called by muse, mutect2, varscan2
- HIBADH | c.*639C>T | 3'UTR (SNP) | VAF 44/68 reads (65%) | catalogued as rs1041567336; called by muse, mutect2, varscan2
- HMGCLL1 | c.*340_*343del | 3'UTR (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- HRH1 | c.*656G>A | 3'UTR (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- ING3 | c.437-15T>G | Intron (SNP) | VAF 40/54 reads (74%) | called by muse, mutect2
- LMBRD2 | c.*3966A>G | 3'UTR (SNP) | VAF 26/92 reads (28%) | catalogued as rs931370208; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851148 T>G | 5'Flank (SNP) | VAF 76/180 reads (42%) | catalogued as rs759140353; called by muse, mutect2, varscan2
- NR6A1 | c.*4838C>T | 3'UTR (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- NRXN1 | c.*2982dup | 3'UTR (INS) | VAF 22/49 reads (45%) | catalogued as rs901732342; called by mutect2, varscan2
- POSTN | c.*712A>T | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- PRDM5 | c.*2231T>G | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- RAI14 | c.36+1263T>C | Intron (SNP) | VAF 334/512 reads (65%) | called by muse, mutect2, varscan2
- RBM6 | c.-67+331_-67+339dup | Intron (INS) | VAF 30/88 reads (34%) | called by mutect2, varscan2
- S1PR2 | c.-43+737G>A | Intron (SNP) | VAF 81/119 reads (68%) | called by muse, mutect2, varscan2
- TAF5L | c.972+615C>T | Intron (SNP) | VAF 70/147 reads (48%) | called by muse, mutect2, varscan2
- TRIM46 | c.1886+413C>T | Intron (SNP) | VAF 40/91 reads (44%) | catalogued as rs550261951; called by muse, mutect2, varscan2
- XIAP | c.*3056T>C | 3'UTR (SNP) | VAF 51/122 reads (42%) | catalogued as rs762740109; called by muse, mutect2, varscan2
